Surgical pathology report (de-identified scan), TCGA case TCGA-D6-6517, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D6-6517-01A (Primary Tumor).

Examination: Histopathological examination

Patient: XXX

TCGA - D6 - 6517

Material: Lesion excision - larynx

Physician in charge:

Material collected on Material received on

Expected time of examination:

Clinical diagnosis: Tumour of the larynx

Examination performed on:

Macroscopic description:

Surgical specimens sized 7.3 x 8.0 x 4.2 cm comprising the larynx with hyoid bone and part of the trachea 1.3 cm in length.

Tumour sized 3.2 x 2.4 x 1.5 cm in the subglottal region invading the false vocal cords and the thyroid cartilage.

Histopathological diagnosis:

Carcinoma planoepitheliale keratodes invasivum (G2) laryngis, pT3. Invasive (G2) planoepithelial carcinoma of the larynx, with keratosis.

Excision lines within healthy tissues.

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 7836ef7e-57f1-4076-8ffe-b8778339e9d3 (TCGA-D6-6517.7773021B-0C32-477C-ACB6-D99B6D958DEE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).